Somatic mutation profile of tumor specimen MMRF_2457_1_BM_CD138pos (aliquot MMRF_2457_1_BM_CD138pos_T1_KHS5U_L11609) from MMRF case MMRF_2457, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.7 years (19,237 days).
Specimen MMRF_2457_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323df579-d675-41ca-ab87-5350b81fd5cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2457_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2457_1_PB_CD3pos_C3_KHS5U_L11610; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f65df97-e5a4-4025-a5db-548b2647bf36

The open-access MAF lists 146 somatic variants for this specimen: 64 protein-altering or splice-affecting, 12 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 35, Intron 21, Silent 12, 5'UTR 8, 3'Flank 3, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 2, 5'Flank 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 46/90 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs936356646; called by muse, mutect2, varscan2
- BNIP5 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.179); catalogued as rs576970172, COSV71325557; called by muse, mutect2, varscan2
- CDK15 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as rs775901921, COSV53638424; called by muse, mutect2, varscan2
- DNAH3 | c.11002C>A p.Q3668K | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as rs1212094414; called by muse, mutect2, varscan2
- EEF2 | c.821_823del p.S274del | In Frame Del (DEL) | VAF 37/119 reads (31%) | catalogued as rs761907521; called by mutect2, pindel, varscan2
- EFHC2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775518457, COSV69553438; called by muse, mutect2, varscan2
- FAM135A | c.607G>A p.V203M (on ENST00000370479 / NM_001351599.1; = p.V160M on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs143901584; called by muse, mutect2, varscan2
- GAN | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs746724274; called by muse, mutect2, varscan2
- GLI4 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs748101436; called by muse, mutect2, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- IGLV3-1 | c.315C>G p.Y105* | Nonsense Mutation (SNP) | VAF 116/232 reads (50%) | catalogued as rs373828762; called by muse, varscan2
- ITGAX | c.2990G>A p.R997Q | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762632993, COSV51646985; called by muse, mutect2, varscan2
- LAMA2 | c.7022T>C p.I2341T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1241629987; called by muse, mutect2, varscan2
- LUZP2 | c.804A>C p.Q268H | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100419385, COSV61195719; called by muse, mutect2, varscan2
- MARK3 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1195446283; called by muse, mutect2, varscan2
- MED26 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs770610103, COSV54659099; called by muse, mutect2, varscan2
- NRXN3 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1162166974; called by muse, mutect2, varscan2
- PIK3CA | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55881772, COSV55902438, COSV55902706; called by muse, mutect2, varscan2
- PLXNA2 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 120/210 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.273); catalogued as rs1373446570; called by muse, mutect2, varscan2
- RYR1 | c.13836G>T p.W4612C | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.75); catalogued as COSV62097332; called by muse, mutect2, varscan2
- TRPM8 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199784199; called by muse, mutect2, varscan2
- AP2B1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ARHGAP35 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ASPSCR1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.539); called by muse, mutect2
- ATP2C1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CCDC174 | c.952+2T>C p.X318_splice | Splice Site (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- CYLD | c.1425G>T p.L475F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- DNAH9 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL5 | c.2315A>G p.H772R | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- FRYL | c.7978A>G p.T2660A | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT1 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HEATR4 | c.1997A>C p.H666P | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- HMGB1 | c.406A>C p.T136P | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- HRK | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- HUWE1 | c.7333G>T p.D2445Y | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HUWE1 | c.6732T>G p.N2244K | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IGF2BP3 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM8 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA2026 | c.5228C>A p.P1743H | Missense Mutation (SNP) | VAF 82/393 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KIF13A | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KRBA2 | c.154T>G p.Y52D | Missense Mutation (SNP) | VAF 110/215 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- LRIG3 | c.1186A>T p.N396Y | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAIP1 | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MRPL2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NCOR1 | c.5430_5433dup p.R1813Lfs*32 | Frame Shift Ins (INS) | VAF 39/72 reads (54%) | called by mutect2, varscan2
- ORC1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PRDM1 | c.1982G>A p.C661Y | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.291T>G p.S97R | Missense Mutation (SNP) | VAF 142/449 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- RING1 | c.171T>A p.N57K | Missense Mutation (SNP) | VAF 120/220 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SETD2 | c.5490dup p.K1831* | Frame Shift Ins (INS) | VAF 78/167 reads (47%) | called by mutect2, pindel, varscan2
- SETD2 | c.518T>A p.L173* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- SLC35F5 | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TG | c.6586G>T p.A2196S | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAF3 | c.176T>A p.V59E | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- TRIP11 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- USP47 | c.2925C>G p.D975E (on ENST00000399455 / NM_001372095.1; = p.D887E on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- WDR97 | c.1548_1559del p.P517_P520del | In Frame Del (DEL) | VAF 63/128 reads (49%) | called by mutect2, pindel, varscan2
- ZC3HAV1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYND15 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 148/251 reads (59%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF205 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF620 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM3 | c.52A>C p.S18R | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FAM47C | c.2316C>A p.S772= | Silent (SNP) | VAF 43/189 reads (23%) | catalogued as COSV63726949; called by muse, mutect2, varscan2
- FBXW10 | c.1479T>A p.G493= | Silent (SNP) | VAF 64/373 reads (17%) | called by muse, mutect2, varscan2
- HTT | c.3592T>C p.L1198= | Silent (SNP) | VAF 54/93 reads (58%) | catalogued as rs762346343; called by muse, mutect2, varscan2
- IGLV3-1 | c.231T>A p.P77= | Silent (SNP) | VAF 90/180 reads (50%) | catalogued as rs558971531; called by muse, varscan2
- LARP6 | c.954G>A p.K318= | Silent (SNP) | VAF 105/219 reads (48%) | called by muse, mutect2, varscan2
- MEFV | c.2103G>A p.A701= | Silent (SNP) | VAF 212/425 reads (50%) | catalogued as rs104895095, COSV54818684; ClinVar: benign / not provided; called by muse, mutect2, varscan2
- MUC16 | c.15804G>C p.T5268= | Silent (SNP) | VAF 76/226 reads (34%) | catalogued as rs768841325, COSV101198873; called by muse, mutect2, varscan2
- NBPF4 | c.1575G>A p.G525= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as rs1357392399; called by muse, varscan2
- PBRM1 | c.3564T>G p.A1188= (on ENST00000296302 / NM_001366071.2; = p.A1163= on NM_018313.5) | Silent (SNP) | VAF 59/106 reads (56%) | called by muse, mutect2, varscan2
- SAE1 | c.753A>T p.T251= | Silent (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- SMARCA1 | c.1674G>A p.E558= | Silent (SNP) | VAF 76/156 reads (49%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.99G>A p.A33= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as rs1221783149, COSV59072034; called by muse, mutect2, varscan2
- ABI2 | c.*1805T>C | 3'UTR (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- ACSL6 | c.196-35T>C | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as rs750067812; called by muse, mutect2, varscan2
- ACTN3 | c.148-109G>T | Intron (SNP) | VAF 119/239 reads (50%) | called by muse, mutect2, varscan2
- AIPL1 | c.*1579C>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- AKAP3 | c.*27T>C | 3'UTR (SNP) | VAF 15/73 reads (21%) | catalogued as rs762690249; called by mutect2, varscan2
- ATRX | c.*2200A>T | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- B4GALT5 | c.*1489A>T | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- BICD2 | c.*1004A>T | 3'UTR (SNP) | VAF 58/102 reads (57%) | catalogued as rs140781395; called by muse, varscan2
- BTBD3 | c.*2535C>A | 3'UTR (SNP) | VAF 58/59 reads (98%) | called by muse, mutect2, varscan2
- C19orf25 | c.130+38G>A | Intron (SNP) | VAF 111/182 reads (61%) | called by muse, mutect2, varscan2
- C6orf62 | c.*943dup | 3'UTR (INS) | VAF 41/111 reads (37%) | called by mutect2, pindel, varscan2
- CHM | c.*1079C>A | 3'UTR (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- CIP2A | c.*6A>G | 3'UTR (SNP) | VAF 51/104 reads (49%) | catalogued as rs1553692323; called by muse, mutect2, varscan2
- CLDN2 | c.-58G>A | 5'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- CLUL1 | c.256-26G>T | Intron (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- CTPS1 | c.1692-52G>A | Intron (SNP) | VAF 87/177 reads (49%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-35+1658G>A | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- EHHADH | c.*550A>G | 3'UTR (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- EIF1AX | c.*1001T>G | 3'UTR (SNP) | VAF 144/328 reads (44%) | called by muse, mutect2, varscan2
- ELOB | c.*236A>G | 3'UTR (SNP) | VAF 58/138 reads (42%) | catalogued as rs1300156045; called by muse, mutect2, varscan2
- ETF1 | c.862+89T>G | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- FAM122C | c.-97C>T | 5'UTR (SNP) | VAF 228/498 reads (46%) | called by muse, mutect2, varscan2
- GIMAP6 | c.86-127G>A | Intron (SNP) | VAF 49/156 reads (31%) | catalogued as rs774763150; called by muse, mutect2, varscan2
- GLIS3 | c.*3648dup | 3'UTR (INS) | VAF 38/100 reads (38%) | catalogued as rs1398329643; called by mutect2, pindel, varscan2
- GSS | c.351+65T>A | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- GTF2E2 | c.*75A>G | 3'UTR (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- GTF2H2C | c.135-113A>C | Intron (SNP) | VAF 10/91 reads (11%) | catalogued as rs335259, COSV66287088; called by muse, mutect2
- HAUS6 | c.*2564A>T | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- IGKV5-2 | c.-45A>G | 5'UTR (SNP) | VAF 53/59 reads (90%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*1527T>G | 3'UTR (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- KLF6 | c.*2111T>C | 3'UTR (SNP) | VAF 60/112 reads (54%) | called by muse, mutect2, varscan2
- KLHL4 | c.*103T>C | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- LCOR | c.*763T>C | 3'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- LRRN3 | c.-297A>G | 5'UTR (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- MARCHF3 | c.*2239A>T | 3'UTR (SNP) | VAF 56/140 reads (40%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851180 C>T | 5'Flank (SNP) | VAF 115/207 reads (56%) | catalogued as rs551757315; called by muse, mutect2, varscan2
- MROH1 | c.1142-7493G>A | Intron (SNP) | VAF 31/61 reads (51%) | catalogued as rs376468888; called by muse, mutect2, varscan2
- NAMPTP1 | n.2203T>C | RNA (SNP) | VAF 20/568 reads (4%) | called by muse, mutect2
- NCSTN | c.85+361G>A | Intron (SNP) | VAF 85/179 reads (47%) | catalogued as rs1341206173; called by muse, mutect2, varscan2
- NTRK3 | c.*9371T>C | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- PDX1 | c.*1279C>A | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- PHF12 | c.-506G>C | 5'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- PKP4 | chr2:158681554 T>G | 3'Flank (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- PTHLH | c.-23+215A>C | Intron (SNP) | VAF 99/200 reads (50%) | called by muse, mutect2, varscan2
- RAB3IP | c.*2800G>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- RBM6 | c.2440-78G>T | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- RGS3 | c.415+1588C>T | Intron (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- RHOB | c.*516C>T | 3'UTR (SNP) | VAF 83/167 reads (50%) | catalogued as rs1482342038; called by muse, mutect2, varscan2
- ROCK1 | c.-89G>A | 5'UTR (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*2656T>C | 3'UTR (SNP) | VAF 47/81 reads (58%) | called by muse, mutect2, varscan2
- SGCE | c.770+33T>C | Intron (SNP) | VAF 40/115 reads (35%) | catalogued as rs1274438244; called by muse, mutect2, varscan2
- SH2D1A | c.-36T>G | 5'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- SNX30 | c.*4082G>A | 3'UTR (SNP) | VAF 49/109 reads (45%) | catalogued as rs188943368; called by muse, mutect2, varscan2
- SPTLC2 | c.*3652A>G | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- STK32A | c.1033-94C>A | Intron (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- SUSD5 | c.*1807C>T | 3'UTR (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- SYNJ2 | c.*688T>C | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- SYT6 | c.*90G>A | 3'UTR (SNP) | VAF 52/96 reads (54%) | catalogued as rs769514569; called by muse, mutect2, varscan2
- TGFB3 | c.*257C>A | 3'UTR (SNP) | VAF 158/323 reads (49%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975590 C>T | 5'Flank (SNP) | VAF 151/319 reads (47%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TMSB4X | chrX:12977131 del AGTTTAATCAG | 3'Flank (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- TRAM2 | c.*844G>C | 3'UTR (SNP) | VAF 88/196 reads (45%) | called by muse, mutect2
- TSN | c.66+77C>T | Intron (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- TSPAN5 | c.*1308A>G | 3'UTR (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- USP25 | c.-298G>C | 5'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- VPS13A | c.6378+262T>G | Intron (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- WDR92 | chr2:68125235 del ACGCC | 3'Flank (DEL) | VAF 72/173 reads (42%) | called by mutect2, pindel, varscan2
- ZNF496 | c.*1603G>A | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- ZNF783 | c.*168+1040_*168+1059del | Intron (DEL) | VAF 18/100 reads (18%) | called by pindel, varscan2
- ZNF783 | c.*168+1063C>G | Intron (SNP) | VAF 16/70 reads (23%) | called by muse, varscan2
